Somatic mutation profile of tumor specimen 0DW2W9 from CCDI case PBCNMZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligoastrocytoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 18.1 years (6,601 days).
Specimen 0DW2W9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e803348-4911-4ba0-aa54-38beb0da441a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW2VO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c167014f-69be-49ac-b0b4-94416ac68aa7

The open-access MAF lists 1,738 somatic variants for this specimen: 1,082 protein-altering or splice-affecting, 451 silent, 205 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,011, Silent 451, Intron 123, 3'UTR 41, Nonsense Mutation 35, 5'UTR 23, Splice Region 19, 5'Flank 9, Splice Site 8, Frame Shift Del 5, 3'Flank 4, RNA 4.

Variants (750 of 1,738; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 116/821 reads (14%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 104/359 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- LAMA2 | c.3085C>T p.R1029* | Nonsense Mutation (SNP) | VAF 157/964 reads (16%) | catalogued as rs145420388, CM020725, COSV101370819; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 39/300 reads (13%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- SCN1A | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 130/1078 reads (12%) | catalogued as rs794726799, CM067015, COSV57667265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2438C>T p.S813L | Missense Mutation (SNP) | VAF 35/646 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795105, COSV60807773; ClinVar: likely pathogenic; called by muse, mutect2
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 22/526 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 116/699 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 278/725 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 18/432 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 36/574 reads (6%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TSHR | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs121908872, CM971536, COSV53321521; ClinVar: likely pathogenic / likely benign; called by muse, mutect2
- ABCA1 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 58/708 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs189206655, COSV66064966; called by muse, mutect2
- ABCA13 | c.1689G>A p.W563* | Nonsense Mutation (SNP) | VAF 26/688 reads (4%) | catalogued as COSV70032926; called by muse, mutect2
- ABCA2 | c.4784G>A p.R1595H (on ENST00000614293; = p.R1565H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as rs1449588556, COSV55800886; called by muse, mutect2, varscan2
- ABCA7 | c.3352C>T p.R1118* | Nonsense Mutation (SNP) | VAF 44/252 reads (17%) | catalogued as rs766318027, COSV54032378; called by muse, mutect2, varscan2
- ABCA9 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 93/783 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs1441880612; called by muse, mutect2, varscan2
- ABCB5 | c.3080G>A p.R1027H (on ENST00000404938 / NM_001163941.2; = p.R582H on NM_178559.6) | Missense Mutation (SNP) | VAF 110/823 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs745749100, COSV51703658, COSV51718688; called by muse, mutect2, varscan2
- ABCC4 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 62/940 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs1415738240, COSV65313177; called by muse, mutect2
- ABCD1 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs782583464; ClinVar: uncertain significance; called by muse, mutect2
- ACACB | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 36/443 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.487); catalogued as rs969688290; called by muse, mutect2
- ACE | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1251602237, COSV52007782, COSV52008955; called by muse, mutect2, varscan2
- ACTN4 | c.2728G>A p.D910N | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs189577008; called by muse, mutect2
- ADAMDEC1 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 99/603 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836364; called by muse, mutect2, varscan2
- ADAMTS12 | c.3697A>G p.T1233A | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs758346879; called by muse, mutect2
- ADAMTS13 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs782206311; called by muse, mutect2, varscan2
- ADAMTS17 | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486295146, COSV51475458, COSV51476046; called by muse, mutect2, varscan2
- ADAMTS19 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 59/609 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs760011119, COSV50733404; called by muse, mutect2, varscan2
- ADAMTSL5 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1438618912, COSV57860551; called by muse, mutect2
- ADCY1 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 114/671 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs781058119, COSV52032726; called by muse, mutect2, varscan2
- ADCY2 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 121/765 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100603438; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366095496; called by muse, mutect2
- ADGRB1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1462113824, COSV60095642, COSV60100138; called by muse, mutect2
- ADGRV1 | c.11674C>T p.R3892W | Missense Mutation (SNP) | VAF 68/934 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as rs766913299, COSV67979727; called by muse, mutect2
- AGO1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 88/708 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as COSV64595407; called by muse, mutect2, varscan2
- AKAP11 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 23/731 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1239904915, COSV50302803; called by muse, mutect2
- AKAP9 | c.10601A>G p.H3534R (on ENST00000359028; = p.H3510R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/948 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.065); catalogued as rs1236620487; called by muse, mutect2
- AKR7L | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 20/369 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1381974610; called by muse, mutect2
- ALDH1L1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 99/522 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV56414592; called by muse, mutect2, varscan2
- AMFR | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 18/664 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.99); catalogued as rs1288021595; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.3400C>T p.R1134C | Missense Mutation (SNP) | VAF 21/672 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1018081322; called by muse, mutect2
- ANKIB1 | c.1720G>A p.V574M | Missense Mutation (SNP) | VAF 72/1052 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs1367246714; called by muse, mutect2
- ANKRD11 | c.6514G>A p.G2172R | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs369545274, COSV99970984; called by muse, mutect2, varscan2
- ANKRD62 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1186904272; called by muse, mutect2
- APCDD1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs374082304; called by muse, mutect2, varscan2
- APCDD1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 32/459 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV62372136; called by muse, mutect2
- APOBEC3F | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 86/609 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs745855767; called by muse, mutect2, varscan2
- APOL2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 50/728 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs371749974; called by muse, mutect2
- ARFGEF2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 92/697 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.274); catalogued as COSV64213761; called by muse, mutect2, varscan2
- ARHGAP24 | c.1714C>T p.R572C (on ENST00000395184 / NM_001025616.3; = p.R479C on NM_031305.3) | Missense Mutation (SNP) | VAF 20/514 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs1176128263; called by muse, mutect2
- ARHGAP35 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 93/585 reads (16%) | catalogued as COSV68334058; called by muse, mutect2, varscan2
- ARHGEF9 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 18/550 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.136); catalogued as COSV99492477; called by muse, mutect2
- ARID1A | c.6694C>T p.R2232W | Missense Mutation (SNP) | VAF 83/537 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61374953, COSV61383222; called by muse, mutect2, varscan2
- ARID1B | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs1278873945; called by muse, varscan2
- ARID1B | c.5383C>T p.R1795C | Missense Mutation (SNP) | VAF 94/567 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs745372243, COSV51649487; called by muse, mutect2, varscan2
- ARID5B | c.2891G>A p.G964D | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV54414257; called by muse, mutect2, varscan2
- ARMC9 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 47/490 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1343090642; called by muse, mutect2, varscan2
- ARVCF | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 50/592 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs376589668; called by muse, mutect2
- ASXL2 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 82/1334 reads (6%) | catalogued as COSV55455792; called by muse, mutect2
- ATG2A | c.4409C>T p.T1470M | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs372670898; called by muse, mutect2, varscan2
- ATG2B | c.4639C>T p.R1547C | Missense Mutation (SNP) | VAF 48/677 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758528785, COSV55889986; called by muse, mutect2
- ATN1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); catalogued as rs140292997; called by muse, mutect2, varscan2
- ATP10A | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755699101; called by muse, mutect2
- ATP1A2 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 70/541 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM082492, COSV63403044; called by muse, mutect2, varscan2
- ATP7B | c.3107T>C p.V1036A | Missense Mutation (SNP) | VAF 24/501 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.247); catalogued as COSV99666898; called by muse, mutect2
- ATP9A | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 57/477 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194861517, COSV58762840, COSV58770385; called by muse, mutect2, varscan2
- ATRX | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 71/974 reads (7%) | catalogued as COSV64873412; called by muse, mutect2
- AVPR2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782128197, COSV100509454; called by muse, mutect2, varscan2
- B4GALNT2 | c.997C>G p.P333A | Missense Mutation (SNP) | VAF 60/586 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.893); catalogued as COSV55928160; called by muse, mutect2, varscan2
- B4GALNT4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.353); catalogued as COSV57327208; called by muse, mutect2
- B4GALNT4 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV57323370; called by muse, mutect2
- BAP1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 97/700 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1553646022, COSV56235508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBS12 | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 102/849 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411645871, COSV58562680; called by muse, mutect2, varscan2
- BBX | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 156/1060 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV100360766; called by muse, mutect2, varscan2
- BCAP31 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 109/632 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs782721594; called by muse, mutect2, varscan2
- BCL9 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs782700818, COSV52342778; called by muse, mutect2, varscan2
- BCLAF1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 40/376 reads (11%) | catalogued as rs759289578, COSV62145348; called by muse, mutect2, varscan2
- BEND5 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 60/1066 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1190968609; called by muse, mutect2
- BFSP2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 34/530 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs142499840; called by muse, mutect2
- BIRC6 | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 64/727 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as rs775469848, COSV101428041; called by muse, mutect2
- BIRC6 | c.12707G>A p.R4236Q | Missense Mutation (SNP) | VAF 154/1096 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs755466134, COSV101427833; called by muse, mutect2, varscan2
- BPIFB1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 59/398 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as rs373099188; called by muse, mutect2, varscan2
- BRAT1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 39/501 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369391505; ClinVar: uncertain significance; called by muse, mutect2
- BRD9 | c.717+2T>C p.X239_splice | Splice Site (SNP) | VAF 24/652 reads (4%) | catalogued as rs1219984897; called by muse, mutect2
- C19orf54 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184492176, COSV99648819; called by muse, mutect2
- C1QTNF7 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 58/970 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs776483061, COSV54850388; called by muse, mutect2
- CACNA1C | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 74/904 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1199713333; called by muse, mutect2
- CACNA1D | c.4046C>T p.A1349V (on ENST00000350061 / NM_001128840.3; = p.A1369V on NM_000720.4) | Missense Mutation (SNP) | VAF 15/389 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1385607389; called by muse, mutect2
- CACNA1E | c.3448G>A p.V1150M | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs546281059; called by muse, mutect2
- CADM4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 39/435 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55928940; called by muse, mutect2
- CALCOCO1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 43/402 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.601); catalogued as rs371607550; called by muse, mutect2
- CARD19 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 76/557 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); catalogued as rs752611032, COSV64936096; called by muse, mutect2, varscan2
- CARD9 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as rs760681802; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARM1 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.27); catalogued as rs909244932; called by muse, mutect2, varscan2
- CASP1 | c.662G>A p.R221H (on ENST00000436863 / NM_033292.4; = p.R200H on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/862 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs142765993; called by muse, mutect2
- CASP14 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 73/414 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs936540103, COSV55664718; called by muse, mutect2, varscan2
- CASP8 | c.1181C>T p.P394L (on ENST00000432109 / NM_033355.3; = p.P411L on NM_001228.4) | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51846287, COSV51861191; called by muse, mutect2, varscan2
- CASR | c.2891G>A p.R964Q (on ENST00000490131; = p.R1041Q on NM_000388.4) | Missense Mutation (SNP) | VAF 68/495 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761580803, COSV56136442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CC2D1A | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 36/554 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs981702503, COSV54310139, COSV99582967; called by muse, mutect2
- CCDC146 | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 48/529 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs372638071; called by muse, mutect2
- CCDC50 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 88/772 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs772943550; called by muse, mutect2
- CCDC57 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 59/372 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as rs777420391, COSV66434283; called by muse, mutect2, varscan2
- CCDC81 | c.1559A>G p.E520G (on ENST00000445632 / NM_001156474.2; = p.E430G on NM_021827.4) | Missense Mutation (SNP) | VAF 66/1017 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99563978; called by muse, mutect2
- CCP110 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 72/663 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs1223158927; called by muse, mutect2, varscan2
- CCT4 | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 56/800 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66701097; called by muse, mutect2
- CCT5 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 159/1006 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs998269335, COSV54724191; called by muse, mutect2, varscan2
- CDC14A | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 117/756 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs376700434; called by muse, mutect2, varscan2
- CDCA7L | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 70/748 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778002499, COSV60938162; called by muse, mutect2
- CDH12 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 154/1048 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs766869658, COSV101202637, COSV66397017; called by muse, mutect2, varscan2
- CDH24 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.79); PolyPhen probably damaging (1); catalogued as rs1257247251; called by muse, mutect2, varscan2
- CDHR2 | c.2171C>T p.T724M | Missense Mutation (SNP) | VAF 53/406 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs113163991; called by muse, mutect2, varscan2
- CDR2L | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61501898; called by muse, mutect2
- CECR2 | c.1727G>A p.R576H (on ENST00000342247 / NM_001290047.2; = p.R393H on NM_001290046.1) | Missense Mutation (SNP) | VAF 87/517 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs921298824; called by muse, mutect2, varscan2
- CEP290 | c.1727A>G p.D576G | Missense Mutation (SNP) | VAF 79/733 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV58349582; called by muse, mutect2, varscan2
- CEP295NL | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 61/445 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs532810670, COSV53163978; called by muse, mutect2, varscan2
- CFAP221 | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 93/682 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1230365309; called by muse, mutect2, varscan2
- CHD3 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 68/812 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs771669987, COSV100390630; called by muse, mutect2
- CHEK1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 70/1397 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749631457, COSV99629877; called by muse, mutect2
- CHERP | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs1341555394, COSV99550059; called by muse, mutect2, varscan2
- CHST6 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs756056122; called by muse, mutect2
- CKMT1A | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 57/514 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs757711456, COSV63256836; called by muse, mutect2, varscan2
- CLCN4 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 43/540 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.658); catalogued as rs779824005, COSV101074134; ClinVar: uncertain significance; called by muse, mutect2
- CLEC16A | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 59/437 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68497894; called by muse, mutect2, varscan2
- CLK3 | c.1513G>A p.V505I (on ENST00000395066 / NM_001130028.1; = p.V357I on NM_003992.4) | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as rs754347798; called by muse, mutect2
- CLRN2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 82/709 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs776701676, COSV55549813; called by muse, mutect2, varscan2
- CNGA4 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV66006352; called by muse, mutect2
- CNOT1 | c.2860G>A p.G954R | Missense Mutation (SNP) | VAF 23/759 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99800868; called by muse, mutect2
- CNRIP1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 89/650 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs768071705; called by muse, mutect2, varscan2
- COL12A1 | c.6074G>A p.R2025H | Missense Mutation (SNP) | VAF 75/578 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs34336755; called by muse, mutect2, varscan2
- COL21A1 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs757819748; called by muse, mutect2
- COL4A6 | c.4175G>A p.G1392D | Missense Mutation (SNP) | VAF 69/569 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57859347; called by muse, mutect2, varscan2
- COPG1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 38/562 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs764991686; called by muse, mutect2
- COX8C | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 26/856 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs1232032663, COSV56373742; called by muse, mutect2
- CPA5 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs782376492, COSV62569564; called by muse, mutect2, varscan2
- CRACDL | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1559212364; called by muse, mutect2
- CRELD2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 24/359 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.045); catalogued as COSV58208246; called by muse, mutect2
- CRISPLD1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 42/1287 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51551479; called by muse, mutect2
- CROCC2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1225010703; called by muse, mutect2, varscan2
- CRTAC1 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 68/483 reads (14%) | catalogued as rs766902119, COSV54005769; called by muse, mutect2, varscan2
- CRTC2 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 78/1026 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1344830341, COSV57842011; called by muse, mutect2
- CSMD2 | c.6743G>A p.R2248Q | Missense Mutation (SNP) | VAF 40/689 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753001856, COSV53892023; called by muse, mutect2
- CSPP1 | c.1579G>A p.A527T (on ENST00000676605; = p.A486T on NM_024790.6) | Missense Mutation (SNP) | VAF 80/1342 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs374214705; called by muse, mutect2
- CSRP3 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 118/615 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs767932680, COSV56389526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CST8 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 87/747 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs374838890; called by muse, mutect2, varscan2
- CTDP1 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 28/512 reads (5%) | catalogued as rs771539643; called by muse, mutect2
- CTNNA1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 114/692 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.906); catalogued as rs373717420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 28/922 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs1195868563, COSV65583983; ClinVar: uncertain significance; called by muse, mutect2
- CUL1 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 65/1140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57390264; called by muse, mutect2
- CYFIP1 | c.1674+7G>A | Splice Region (SNP) | VAF 43/278 reads (15%) | catalogued as rs571760306; called by muse, mutect2, varscan2
- CYFIP1 | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 35/423 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1258355371; called by muse, mutect2
- CYP2D6 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 61/512 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs993385303; called by muse, varscan2
- DAB2IP | c.2401C>T p.R801W (on ENST00000408936; = p.R773W on NM_032552.3) | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs927107583; called by muse, mutect2, varscan2
- DCBLD1 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 108/656 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748126092; called by muse, mutect2, varscan2
- DCC | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 173/1171 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV59086256; called by muse, mutect2, varscan2
- DCHS1 | c.4658G>A p.R1553H | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.684); catalogued as COSV55036469; called by muse, mutect2, varscan2
- DCSTAMP | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 37/796 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV52575818, COSV99034295; called by muse, mutect2
- DCTN2 | c.514G>A p.A172T (on ENST00000548249 / NM_001261413.2; = p.A177T on NM_006400.4) | Missense Mutation (SNP) | VAF 96/528 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.908); catalogued as rs779229455, COSV100851896; called by muse, mutect2, varscan2
- DDI1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 44/633 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs765905483, COSV56373167; called by muse, mutect2
- DDR1 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.613); catalogued as rs748609770; called by muse, mutect2
- DEF6 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 72/554 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as rs1434952535; called by muse, mutect2, varscan2
- DENND5B | c.3730C>T p.R1244C | Missense Mutation (SNP) | VAF 78/511 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs778218082, COSV100171577; called by muse, varscan2
- DEPDC1B | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 37/536 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV54008880; called by muse, mutect2
- DHX38 | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 90/606 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs766544740; called by muse, mutect2, varscan2
- DHX9 | c.3478C>T p.R1160C | Missense Mutation (SNP) | VAF 106/716 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs1327282020; called by muse, mutect2, varscan2
- DISP2 | c.3512G>A p.R1171H | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs149742212; called by muse, mutect2, varscan2
- DISP3 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as rs1169708893; called by muse, mutect2
- DLG5 | c.4046G>A p.R1349H | Missense Mutation (SNP) | VAF 30/457 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762391739, COSV64946751; called by muse, mutect2
- DMRT2 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 89/518 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs142906421, COSV52402232; called by muse, mutect2, varscan2
- DMXL2 | c.1034A>G p.Q345R | Missense Mutation (SNP) | VAF 68/1062 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs1244336807; called by muse, mutect2
- DNAH17 | c.7021G>A p.D2341N | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs371184538; called by muse, mutect2, varscan2
- DNAH17 | c.5536G>A p.A1846T | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs752790825; called by mutect2, varscan2
- DNAH5 | c.13852G>A p.A4618T | Missense Mutation (SNP) | VAF 52/886 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54209002; called by muse, mutect2
- DNAJC11 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 50/630 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1553126523, COSV50010564; called by muse, mutect2
- DOCK7 | c.2278C>T p.R760* | Nonsense Mutation (SNP) | VAF 56/870 reads (6%) | catalogued as COSV99225489; called by muse, mutect2
- DPAGT1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 83/536 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs397515327, CM122210; called by muse, mutect2, varscan2
- DUOX1 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772812512, COSV58477078, COSV58481199; called by muse, mutect2, varscan2
- DYRK1A | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs781697806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECPAS | c.4391G>A p.S1464N | Missense Mutation (SNP) | VAF 135/980 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as COSV52200949; called by muse, mutect2, varscan2
- EDAR | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 68/462 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.985); catalogued as rs772418418; called by muse, varscan2
- EEF2KMT | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 73/506 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs760472451; called by muse, mutect2, varscan2
- EGLN2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs139802237; called by muse, mutect2, varscan2
- EIF2B4 | c.875G>A p.R292Q (on ENST00000347454 / NM_001034116.2; = p.R291Q on NM_015636.3) | Missense Mutation (SNP) | VAF 58/805 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.23); catalogued as rs758251555; called by muse, mutect2
- ELAVL3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 74/486 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs1407899639, COSV63648569; called by muse, mutect2, varscan2
- ELL3 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 42/452 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs137982948, COSV55855812; called by muse, mutect2
- ELP1 | c.3032G>A p.R1011H | Missense Mutation (SNP) | VAF 52/592 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs368999377; ClinVar: uncertain significance; called by muse, mutect2
- EP400 | c.4900C>T p.R1634* | Nonsense Mutation (SNP) | VAF 65/430 reads (15%) | catalogued as COSV100201380; called by muse, mutect2, varscan2
- EPHB2 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 93/645 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777155810, COSV65861359; called by muse, mutect2, varscan2
- EPN3 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 44/345 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1360071489, COSV99277066; called by muse, mutect2, varscan2
- EPS15L1 | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 16/429 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs1309144013; called by muse, mutect2
- EPS8 | c.2123A>G p.K708R | Missense Mutation (SNP) | VAF 28/900 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.413); catalogued as rs1359117212; called by muse, mutect2
- ERCC2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs765839639, COSV55541787; called by muse, mutect2, varscan2
- ERG | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 62/452 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.066); catalogued as rs1375725814; called by muse, mutect2, varscan2
- ERG28 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 49/404 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs751084984, COSV53162238; called by muse, mutect2, varscan2
- ETV5 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 82/890 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs767684440, COSV60500669; called by muse, mutect2
- EVC | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 52/553 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs753720935; ClinVar: uncertain significance; called by muse, mutect2
- EXOC4 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 53/881 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs775034999, COSV54089612; called by muse, mutect2
- F2 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs961354543, CM052875, COSV61317475; called by muse, mutect2, varscan2
- F2RL1 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 25/467 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs1280444579; called by muse, mutect2
- FAM171A2 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 44/651 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1246232902; called by muse, mutect2
- FAM200B | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 108/1053 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1178148940, COSV101435846; called by muse, mutect2
- FAM47C | c.2275G>A p.V759I | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.636); catalogued as rs782157463, COSV100793090, COSV63726844; called by muse, mutect2
- FAM83G | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs776432523, COSV58756642; called by muse, mutect2, varscan2
- FAM83H | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1554622903; called by muse, mutect2
- FARP2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 86/619 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs199738844; called by muse, mutect2, varscan2
- FAT1 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1006561183, COSV101499218; called by muse, mutect2
- FAT3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 56/1021 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs534147854; called by muse, mutect2
- FAT4 | c.13891G>A p.A4631T | Missense Mutation (SNP) | VAF 75/594 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748276944, COSV58686919; called by muse, mutect2, varscan2
- FBLN2 | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs750171159; called by muse, mutect2
- FBXW11 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 50/838 reads (6%) | catalogued as rs995419585, COSV51605516; called by muse, mutect2
- FFAR2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 23/366 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409706065, COSV55832400; called by muse, mutect2
- FGL1 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 65/854 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1271559719; called by muse, mutect2
- FHOD3 | c.2902G>A p.A968T (on ENST00000359247 / NM_001281739.3; = p.A985T on NM_025135.5) | Missense Mutation (SNP) | VAF 99/638 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs746707013, COSV57183362; called by muse, mutect2, varscan2
- FLRT3 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 46/648 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99427828; called by muse, mutect2
- FOXN4 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 53/352 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs144504080; called by muse, mutect2
- FOXO1 | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 101/720 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV65428677; called by muse, mutect2, varscan2
- FOXO3 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 75/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369304108; called by muse, mutect2, varscan2
- FRMD8 | c.1074C>T p.A358= | Splice Region (SNP) | VAF 29/253 reads (11%) | catalogued as rs533905084; called by muse, mutect2, varscan2
- FRMPD3 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 100/968 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs755121793, COSV52194564; called by muse, mutect2, varscan2
- FSBP | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 46/855 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1292880868, COSV52594030; called by muse, mutect2
- FXR2 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs762687266; called by muse, mutect2, varscan2
- GALR2 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); catalogued as rs1388831156; called by muse, mutect2
- GALR3 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs1255200108; called by muse, mutect2, varscan2
- GAPT | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 98/570 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148170353, COSV59246909; called by muse, mutect2, varscan2
- GBE1 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 151/980 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770819412; called by muse, mutect2, varscan2
- GDAP1L1 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 76/443 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1352706215, COSV61156439; called by muse, mutect2, varscan2
- GEMIN7 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 49/470 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs369264922, COSV54319383; called by muse, mutect2, varscan2
- GPAA1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 48/402 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.06); catalogued as rs372419360; called by muse, varscan2
- GPATCH1 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 69/456 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs769898388; called by muse, mutect2, varscan2
- GPR149 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 60/808 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV67666950; called by muse, mutect2
- GPR155 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 24/804 reads (3%) | catalogued as rs1466752783, COSV55037072; called by muse, mutect2
- GPR173 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs782281124; called by muse, mutect2, varscan2
- GPR180 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 84/604 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs773974365, COSV65385411; called by muse, mutect2, varscan2
- GPR45 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1289396618, COSV51524828; called by muse, mutect2
- GPR63 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 84/1022 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV57740026; called by muse, mutect2
- GPR78 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.182); catalogued as rs752766314, COSV66764111; called by muse, mutect2
- GPRIN1 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 53/380 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1407864927, COSV56146491; called by muse, mutect2, varscan2
- GPX2 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 71/527 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs200567114; called by muse, mutect2, varscan2
- GRAMD1A | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs200063858; called by muse, mutect2, varscan2
- GRAMD1B | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 24/568 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as rs959228537; called by muse, mutect2
- GRIN2B | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 81/627 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772078838, COSV74204997; called by muse, mutect2, varscan2
- GRIN3A | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 27/752 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62450324; called by muse, mutect2
- GRM1 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 48/674 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as rs752974265, COSV51274803, COSV99269628; called by muse, mutect2
- GRM1 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230617012, COSV51326317; called by muse, mutect2
- GRM5 | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 47/514 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1471625539, COSV59597532; called by muse, mutect2
- GTPBP6 | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 52/384 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as rs1470761299; called by muse, mutect2, varscan2
- GYS1 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as rs573897595, COSV54405076; ClinVar: uncertain significance; called by muse, mutect2
- GZMB | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 29/348 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs564414889, COSV53543375, COSV53543682; called by muse, mutect2
- H1-7 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 17/349 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1361775815, COSV58601626; called by muse, mutect2
- HAND2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs867226231, COSV64017614; called by muse, mutect2, varscan2
- HLX | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 28/769 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV65045799; called by muse, mutect2
- HMGB3 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 38/612 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs781926483; called by muse, mutect2
- HMX1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as rs929420675; called by muse, varscan2
- HPSE2 | c.938T>A p.V313D | Missense Mutation (SNP) | VAF 38/800 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV65186006; called by muse, mutect2
- HSD3B7 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 35/485 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs745915447, COSV52679873; called by muse, mutect2
- HSPG2 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 30/483 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754060584, COSV65978252; called by muse, mutect2
- HTR1D | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 64/419 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as rs41268111, COSV58448220; called by muse, mutect2, varscan2
- ICAM5 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 59/336 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as rs761293492, COSV55747446; called by muse, mutect2, varscan2
- IDUA | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 50/602 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs112571714; called by muse, mutect2
- IGF2BP3 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 139/858 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.745); catalogued as rs202212306; called by muse, mutect2, varscan2
- IGSF1 | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 145/692 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1293600466, COSV63836891; called by muse, mutect2, varscan2
- IGSF21 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 52/686 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774817306, COSV52125830; called by muse, mutect2
- IKZF1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 61/391 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV58786109, COSV58790192; called by muse, mutect2, varscan2
- IL21 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 96/876 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs141748932; called by muse, mutect2, varscan2
- IL36RN | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 62/572 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs767435510, COSV61011052; called by muse, mutect2, varscan2
- ILDR1 | c.821A>G p.Q274R (on ENST00000344209 / NM_001199799.2; = p.Q230R on NM_175924.4) | Missense Mutation (SNP) | VAF 71/542 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs748934361; called by muse, mutect2, varscan2
- ILVBL | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 32/455 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373514197; called by muse, mutect2
- IMPDH1 | c.962G>A p.R321H (on ENST00000470772 / NM_001142573.2; = p.R407H on NM_000883.4) | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs1313564718; called by muse, mutect2
- INPP5A | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 35/447 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.094); catalogued as rs576088004, COSV61253693; called by muse, mutect2
- INPP5D | c.1342G>A p.V448M (on ENST00000445964 / NM_001017915.3; = p.V447M on NM_005541.5) | Missense Mutation (SNP) | VAF 39/521 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64035367; called by muse, mutect2
- IQCN | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs1224160039; called by muse, mutect2
- IRS1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs773817315, COSV59333601, COSV59335611; called by muse, mutect2, varscan2
- ITGA11 | c.1391G>A p.S464N | Missense Mutation (SNP) | VAF 30/522 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1254942640; called by muse, mutect2
- ITGB5 | c.2339C>T p.T780M | Missense Mutation (SNP) | VAF 179/1112 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753887963; called by muse, mutect2, varscan2
- ITPRIPL1 | c.967C>T p.R323W (on ENST00000439118 / NM_001008949.3; = p.R331W on NM_178495.6) | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs145512131; called by muse, mutect2, varscan2
- ITSN1 | c.4238C>T p.A1413V | Missense Mutation (SNP) | VAF 75/634 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs749530031, COSV101181022; called by muse, mutect2, varscan2
- JAK3 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 25/627 reads (4%) | catalogued as rs1198251679, CM012988, COSV101512995; called by muse, mutect2
- JAKMIP1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201482171, COSV51523091; called by muse, mutect2, varscan2
- JHY | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as rs770707669, COSV56221928; called by muse, mutect2
- JMJD6 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 56/975 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs767092762; called by muse, mutect2
- KCNA5 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1343401682, COSV52904676; ClinVar: uncertain significance; called by muse, mutect2
- KCNAB3 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs745315114, COSV58140255; called by muse, mutect2, varscan2
- KCND1 | c.1375G>A p.G459S | Missense Mutation (SNP) | VAF 50/365 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); catalogued as rs782679992; called by muse, mutect2, varscan2
- KCND3 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs1271251092, COSV56183610, COSV56190019; called by muse, mutect2, varscan2
- KCNF1 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs1263315544; called by muse, mutect2, varscan2
- KCNG4 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369952898; called by muse, mutect2, varscan2
- KCNH7 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 50/858 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs149962897, COSV59799471; called by muse, mutect2
- KCNJ10 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 23/691 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194350781, COSV63634260; called by muse, mutect2
- KCTD19 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 34/588 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1403214260, COSV100431231; called by muse, mutect2
- KDM2B | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 17/467 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201860652; called by muse, mutect2
- KDM4D | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 28/778 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs781783527, COSV58635901; called by muse, mutect2
- KDM5C | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 36/956 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV64763692; called by muse, mutect2
- KDM6A | c.3256A>G p.T1086A | Missense Mutation (SNP) | VAF 88/756 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV65042863; called by muse, mutect2, varscan2
- KHSRP | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.07); catalogued as rs779255957, COSV67919582; called by muse, varscan2
- KIF1C | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 75/567 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs150602558; called by muse, mutect2
- KIF26B | c.5015C>T p.A1672V | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs746379050; called by muse, mutect2
- KIF4A | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 77/392 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs149300695; called by muse, mutect2, varscan2
- KIF4B | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 89/719 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as rs758992898, COSV101469213, COSV70530872; called by muse, mutect2, varscan2
- KIRREL3 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 22/677 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.863); catalogued as rs914855096; called by muse, mutect2
- KLC1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as rs760362554; called by muse, mutect2, varscan2
- KLHL13 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 48/652 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.727); catalogued as rs774316250; called by muse, mutect2
- KLHL18 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 77/432 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs994549495, COSV51748196; called by muse, mutect2, varscan2
- KMT2C | c.14018G>A p.R4673H | Missense Mutation (SNP) | VAF 48/790 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151112171; called by muse, mutect2
- KMT2C | c.5113C>T p.R1705C | Missense Mutation (SNP) | VAF 58/559 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1405586437, COSV51459039; called by muse, mutect2, varscan2
- KMT2D | c.3976C>T p.R1326W | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs886049484, COSV56416503; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1298153579; called by muse, mutect2
- KMT5A | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 42/649 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs778079536; called by muse, mutect2
- KPNA2 | c.667-8T>C | Splice Region (SNP) | VAF 47/393 reads (12%) | catalogued as rs782313934, COSV104398759; called by muse, mutect2, varscan2
- KRT14 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 28/670 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs1420455277, COSV99391022; called by muse, mutect2
- KRT20 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 79/736 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs371817674; called by muse, mutect2, varscan2
- KRT37 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 22/634 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs757115917, COSV56657889; called by muse, mutect2
- KRTAP16-1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs557771528, COSV66939150; called by muse, mutect2, varscan2
- KRTAP4-9 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs756953992; called by muse, varscan2
- KSR2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.255); catalogued as rs1243541251; called by muse, mutect2
- L1CAM | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs782756293, COSV62830614; ClinVar: uncertain significance; called by muse, mutect2
- LAMA4 | c.4492C>T p.R1498C (on ENST00000230538 / NM_001105206.3; = p.R1491C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/590 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs782368185, COSV57898099; called by muse, mutect2
- LAMA5 | c.9478G>A p.A3160T | Missense Mutation (SNP) | VAF 77/460 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as rs148384450; called by muse, mutect2, varscan2
- LCE2B | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 54/852 reads (6%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV64227396; called by muse, mutect2
- LDHD | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1489209002; called by muse, mutect2
- LHX5 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55662713; called by muse, mutect2, varscan2
- LIF | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 68/416 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs868113406; called by muse, varscan2
- LLGL2 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV51365872; called by muse, mutect2
- LLGL2 | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1019147525; called by muse, mutect2
- LMTK2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 45/666 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs772440680, COSV52005120; called by muse, mutect2
- LONP1 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 32/517 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs777009012, CM156332; called by muse, mutect2
- LONRF1 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 102/730 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248407696, COSV68036383, COSV68038181; called by muse, mutect2, varscan2
- LRCH3 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 89/684 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs748579801; called by muse, mutect2, varscan2
- LRGUK | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 127/832 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751565610, COSV53633960; called by muse, mutect2, varscan2
- LRIG1 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 112/648 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs746564559, COSV56236777; called by muse, mutect2, varscan2
- LRP1 | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 54/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54510175; called by muse, mutect2, varscan2
- LRP1 | c.11890G>A p.A3964T | Missense Mutation (SNP) | VAF 72/487 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs147095966; called by muse, mutect2, varscan2
- LRP10 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs1271330364, COSV62078853; called by muse, varscan2
- LRP12 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 60/1098 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.146); catalogued as rs373363011; called by muse, mutect2
- LRP1B | c.4495A>G p.T1499A | Missense Mutation (SNP) | VAF 42/1098 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV101260170; called by muse, mutect2
- LRRC38 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 56/488 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs944896039, COSV65791119; called by muse, mutect2, varscan2
- LRRC43 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs773144736, COSV60288150; called by muse, mutect2
- LRRC47 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 47/363 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1232307625, COSV65563409; called by muse, mutect2, varscan2
- LRWD1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1158653902, COSV52961135; called by muse, mutect2, varscan2
- LSG1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 96/662 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763071707, COSV54569510; called by muse, mutect2, varscan2
- LSM14A | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 38/492 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1366855901; called by muse, mutect2
- MACF1 | c.14768G>T p.W4923L (on ENST00000372915; = p.W2856L on NM_012090.5) | Missense Mutation (SNP) | VAF 34/776 reads (4%) | catalogued as COSV57142432; called by muse, mutect2
- MAGEB1 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 42/452 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.516); catalogued as rs745591739, COSV66776278, COSV66776367; called by muse, mutect2
- MAGEE1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100819249; called by muse, mutect2
- MAGIX | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 94/510 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.221); catalogued as COSV66255700; called by muse, mutect2, varscan2
- MALRD1 | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 50/752 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs1266754856, COSV65988171, COSV65998042; called by muse, mutect2
- MAP1S | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.258); catalogued as rs931929421; called by muse, mutect2
- MAP3K10 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs775129430, COSV53423632; called by muse, varscan2
- MAP3K5 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 89/626 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs374880750; called by muse, mutect2, varscan2
- MAPK15 | c.1203C>T p.H401= | Splice Region (SNP) | VAF 15/337 reads (4%) | catalogued as rs201573280, COSV100567873; called by muse, mutect2
- MARCHF7 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 60/991 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.124); catalogued as rs761378095, COSV99373775; called by muse, mutect2
- MARK4 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 54/424 reads (13%) | catalogued as rs1375220874; called by muse, varscan2
- MAST2 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 84/505 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs202035324, COSV63621295; called by muse, mutect2, varscan2
- MB21D2 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 25/484 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs1393817405; called by muse, mutect2
- MCC | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1228302491, COSV99043676; called by muse, mutect2
- MCPH1 | c.1179G>T p.R393S | Missense Mutation (SNP) | VAF 52/683 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369922796, CD133214; called by muse, mutect2
- MEF2B | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs757104393, COSV50762241; called by muse, mutect2, varscan2
- METTL24 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1424696836; called by muse, mutect2
- MGRN1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.377); catalogued as rs372657927; called by muse, mutect2, varscan2
- MICU1 | c.775C>T p.R259C (on ENST00000361114 / NM_001195518.2; = p.R265C on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/786 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367648335; called by muse, mutect2
- MITF | c.554C>T p.T185M (on ENST00000448226 / NM_006722.3; = p.T79M on NM_000248.4) | Missense Mutation (SNP) | VAF 70/576 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs925747808, COSV58834820; called by muse, mutect2, varscan2
- MLXIPL | c.2440+3A>G | Splice Region (SNP) | VAF 30/202 reads (15%) | catalogued as COSV57670804; called by muse, mutect2, varscan2
- MMEL1 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs866976874; called by muse, mutect2, varscan2
- MPHOSPH8 | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 78/435 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs763545081; called by muse, mutect2, varscan2
- MRO | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 94/631 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99838986; called by muse, mutect2, varscan2
- MS4A14 | c.1290A>G p.I430M | Missense Mutation (SNP) | VAF 95/759 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs1335361778; called by muse, mutect2, varscan2
- MTOR | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 92/721 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1228231098, COSV63878574; called by muse, mutect2, varscan2
- MUC17 | c.9695C>T p.T3232M | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs548952598, COSV60282712; called by muse, mutect2, varscan2
- MYBPH | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs749355783, COSV55142306; called by muse, mutect2
- MYBPHL | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 54/714 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs201690316, COSV64062167; called by muse, mutect2
- MYC | c.184T>C p.S62P (on ENST00000377970; = p.S77P on NM_002467.6) | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV52375575, COSV52376842, COSV99419997; called by muse, mutect2, varscan2
- MYO1D | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 104/812 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1366755677, COSV59006869; called by muse, mutect2, varscan2
- MYO1E | c.1486A>G p.N496D | Missense Mutation (SNP) | VAF 23/779 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.405); catalogued as COSV55689464; called by muse, mutect2
- MYOM2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 59/380 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as rs1035230559, COSV50704762, COSV50797420; called by muse, mutect2, varscan2
- MYT1L | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV101221622; called by muse, mutect2
- NALCN | c.5161A>G p.T1721A | Missense Mutation (SNP) | VAF 104/749 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.023); catalogued as COSV51946665; called by muse, mutect2, varscan2
- NAPRT | c.567C>T p.G189= | Splice Region (SNP) | VAF 10/165 reads (6%) | catalogued as rs1179007077; called by muse, mutect2
- NAT10 | c.2471G>A p.R824Q | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199507528; called by muse, mutect2
- NAV2 | c.856G>A p.A286T (on ENST00000396087 / NM_001244963.2; = p.A263T on NM_145117.5) | Missense Mutation (SNP) | VAF 52/620 reads (8%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as rs747098080, COSV100585043; called by muse, mutect2
- NAV3 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 84/1146 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs754878822, COSV99892000, COSV99894324; called by muse, mutect2
- NCBP3 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 53/419 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs184111975, COSV50110340; called by muse, mutect2, varscan2
- NCKAP5L | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757901161; called by muse, mutect2, varscan2
- NEB | c.7697G>A p.R2566Q | Missense Mutation (SNP) | VAF 52/1018 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs564304837, COSV99417922; called by muse, mutect2
- NELFCD | c.1013G>A p.R338H (on ENST00000602795; = p.R320H on NM_198976.4) | Missense Mutation (SNP) | VAF 56/786 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs775433597, COSV53884311; called by muse, mutect2
- NEPRO | c.1567A>T p.I523F | Missense Mutation (SNP) | VAF 140/1412 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV55607044; called by muse, mutect2
- NHLH1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1296749810; called by muse, mutect2
- NIN | c.5264C>T p.A1755V (on ENST00000382041 / NM_182946.1; = p.A1042V on NM_016350.4) | Missense Mutation (SNP) | VAF 78/1260 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as rs758555048, COSV55389524; ClinVar: uncertain significance; called by muse, mutect2
- NIPA2 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 123/871 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1313271562; called by muse, mutect2, varscan2
- NR3C2 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 64/1080 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60987587; called by muse, mutect2
- NSD3 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 42/862 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1250796714, COSV57619196; called by muse, mutect2
- NTN3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142537973; called by muse, mutect2
- NUP133 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 75/1030 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as rs756821853; called by muse, mutect2
- NUP62CL | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 94/765 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs752342907, COSV65235097; called by muse, mutect2, varscan2
- NXN | c.1226A>G p.D409G | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100403041; called by muse, mutect2, varscan2
- NXPE1 | c.566C>T p.A189V (on ENST00000424269; = p.A47V on NM_152315.5) | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760378519, COSV52627100; called by muse, mutect2, varscan2
- NYAP1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs760509943; called by muse, mutect2
- NYAP2 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1039068937, COSV56006471, COSV99797136; called by muse, mutect2, varscan2
- OAS1 | c.654+6G>A | Splice Region (SNP) | VAF 86/519 reads (17%) | catalogued as rs759971092; called by muse, mutect2, varscan2
- OBSCN | c.9289G>A p.V3097I | Missense Mutation (SNP) | VAF 52/379 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs190491710, COSV52750257; called by muse, mutect2, varscan2
- OLAH | c.572C>T p.T191I (on ENST00000378228 / NM_001039702.3; = p.T244I on NM_018324.3) | Missense Mutation (SNP) | VAF 68/503 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs141933979; called by muse, mutect2, varscan2
- OR11H2 | c.770G>A p.S257N (on ENST00000556246; = p.S268N on NM_001197287.1) | Missense Mutation (SNP) | VAF 95/723 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1468113010; called by muse, mutect2, varscan2
- OR2L13 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 98/797 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs948032044, COSV63551913; called by muse, mutect2, varscan2
- OR4A5 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 90/605 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); catalogued as rs182131902; called by muse, mutect2, varscan2
- OR51A7 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 46/631 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1244453067; called by muse, mutect2
- OR8G5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 63/579 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.664); catalogued as rs148046413, COSV58383102; called by muse, mutect2, varscan2
- OR9I1 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 119/526 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV56925735; called by muse, mutect2, varscan2
- OSBPL3 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 42/537 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as rs145677429; called by muse, mutect2
- OSBPL5 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1289992085; called by muse, mutect2, varscan2
- OSM | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 68/1037 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199826579, COSV53161750; called by muse, mutect2
- OTOG | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 56/723 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs901675098; called by muse, mutect2
- OXTR | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57481295; called by muse, mutect2
- P3H2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 119/930 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs780816013, COSV60022702; called by muse, mutect2, varscan2
- P3H3 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs781976830; called by muse, mutect2, varscan2
- PAK4 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs373168150; called by mutect2, varscan2
- PCDH11X | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 48/912 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV53470362, COSV53501091; called by muse, mutect2
- PCDHA3 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.877); catalogued as rs1290587407, COSV100793021; called by muse, mutect2
- PCDHA3 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 23/401 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV63540376; called by muse, mutect2
- PCDHB11 | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.185); catalogued as rs1554285778; called by muse, mutect2
- PCDHB3 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 66/496 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.218); catalogued as COSV50565125; called by muse, varscan2
- PCDHB9 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1282920933; called by muse, mutect2
- PCDHB9 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); catalogued as rs782419413; called by muse, mutect2, varscan2
- PCDHGA7 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs919957351, COSV53941030; called by muse, mutect2
- PCDHGA8 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV53984526; called by muse, mutect2, varscan2
- PCNX2 | c.5150C>T p.A1717V | Missense Mutation (SNP) | VAF 52/628 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99265471; called by muse, mutect2
- PDCD1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.875); catalogued as rs764852072; called by muse, mutect2, varscan2
- PDCD11 | c.4612G>A p.A1538T | Missense Mutation (SNP) | VAF 26/637 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs988670015, COSV99588590; called by muse, mutect2
- PDCD4 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 84/616 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375978756, COSV99701258; called by muse, mutect2, varscan2
- PDE1C | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 63/882 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.383); catalogued as rs143340385; called by muse, mutect2
- PDE1C | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 82/1075 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as COSV58516370; called by muse, mutect2
- PDK2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 69/425 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs752026536; called by muse, mutect2, varscan2
- PGAM4 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 44/655 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs147487697, COSV58442771; called by muse, mutect2
- PGM5 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 109/825 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs771137682, COSV67169072; called by muse, mutect2, varscan2
- PGS1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 30/309 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs767437531; called by muse, mutect2
- PHF5A | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 68/768 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV53439599; called by muse, mutect2
- PHLDB2 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 81/545 reads (15%) | catalogued as rs1245705572; called by muse, mutect2, varscan2
- PHLPP1 | c.4316C>T p.A1439V | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs1003299269; called by muse, mutect2, varscan2
- PI4KA | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 50/652 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs751633032; called by muse, mutect2
- PIEZO1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs911683642; called by muse, mutect2, varscan2
- PIGO | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs551682667, COSV53053228; called by muse, mutect2
- PIK3CA | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 126/921 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242945375, CM126697, COSV55909501; called by muse, mutect2, varscan2
- PKHD1L1 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 66/720 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs200017885, COSV65742348; called by muse, mutect2
- PLAT | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 80/573 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs115997172; called by muse, mutect2, varscan2
- PLCB4 | c.2847A>G p.E949= | Splice Region (SNP) | VAF 68/1034 reads (7%) | catalogued as rs1255447107; called by muse, mutect2
- PLCD3 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs958052474; called by muse, mutect2, varscan2
- PLCXD2 | c.797T>A p.I266N | Missense Mutation (SNP) | VAF 82/765 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67340198; called by muse, mutect2, varscan2
- PLEKHA7 | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 81/664 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755033176, COSV60580322; called by muse, mutect2, varscan2
- PLXNA1 | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 51/384 reads (13%) | catalogued as rs371434286, COSV52524439; called by muse, mutect2, varscan2
- PNN | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 83/1326 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs771154306; called by muse, mutect2
- POLG | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 38/429 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs779353857, COSV51520831; ClinVar: uncertain significance; called by muse, mutect2
- POMK | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 37/674 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.346); catalogued as COSV100505837; called by muse, mutect2
- PPEF2 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 63/519 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs774989139, COSV54420643, COSV54425047; called by muse, mutect2, varscan2
- PPP1R12A | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 49/1170 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV54112584; called by muse, mutect2
- PPP1R36 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 55/754 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751571174, COSV100072673; called by muse, mutect2
- PRDM2 | c.4443A>C p.K1481N | Missense Mutation (SNP) | VAF 60/1160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52451259; called by muse, mutect2
- PRDX3 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 49/746 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as rs779344159, COSV53719178; called by muse, mutect2
- PRG2 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as rs151198699, COSV61293488; called by muse, mutect2, varscan2
- PRKAG3 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as rs570196271, COSV99291927; called by muse, mutect2
- PROM1 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 93/659 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.125); catalogued as rs771239030; called by muse, mutect2, varscan2
- PROSER2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753912940; called by muse, mutect2
- PRPS1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 61/556 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65054243; called by mutect2, varscan2
- PRSS21 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs894960562, COSV50051974; called by muse, mutect2
- PTBP1 | c.995C>T p.A332V (on ENST00000349038 / NM_031991.4; = p.A358V on NM_002819.5) | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs758317861; called by muse, mutect2
- PTK7 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 61/479 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1288366106; called by muse, mutect2, varscan2
- PTOV1 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 29/447 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377067186, COSV99681829; called by muse, mutect2
- PTPRF | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.16); catalogued as rs1189049815, COSV63442919; called by muse, mutect2, varscan2
- RABGEF1 | c.1150G>A p.A384T (on ENST00000439720 / NM_001287061.2; = p.A371T on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/896 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs757460921, COSV53163751; called by muse, mutect2, varscan2
- RAD52 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 68/539 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs371200462; called by muse, mutect2, varscan2
- RALGAPA2 | c.5495+3A>G | Splice Region (SNP) | VAF 29/470 reads (6%) | catalogued as rs1450219067; called by muse, mutect2
- RANBP10 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.846); catalogued as rs774290904, COSV58160439; called by muse, mutect2, varscan2
- RBBP9 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 43/990 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1444081102, COSV61499704; called by muse, mutect2
- RBM28 | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 63/972 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs766526334, COSV99776004; called by muse, mutect2
- RBMXL3 | c.2875G>A p.A959T | Missense Mutation (SNP) | VAF 20/315 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1436904882, COSV57753121; called by muse, mutect2
- RBP5 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 58/548 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as rs1404777697; called by muse, mutect2, varscan2
- RC3H1 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 44/735 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs765310014, COSV51207058; called by muse, mutect2
- RC3H2 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 72/605 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1321951961; called by muse, mutect2, varscan2
- RGL1 | c.433G>A p.A145T (on ENST00000360851 / NM_001297672.2; = p.A180T on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/744 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.624); catalogued as rs1388410955, COSV58996980; called by muse, mutect2
- RGPD8 | c.2861G>A p.R954Q | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769760514, COSV56899894; called by muse, mutect2
- RGS12 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 93/684 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.286); catalogued as rs767834326; called by muse, mutect2, varscan2
- RGS19 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs1410325368, COSV58657143; called by muse, mutect2, varscan2
- RHO | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 85/493 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs118173887, CM1211096; called by muse, mutect2, varscan2
- RHOBTB3 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 135/998 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368331385; called by muse, mutect2, varscan2
- RIMS1 | c.1516T>C p.S506P | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as rs890931277; called by muse, mutect2
- RIMS1 | c.4795A>C p.T1599P | Missense Mutation (SNP) | VAF 86/1167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99330343; called by muse, mutect2
- RIMS4 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs778633514; called by muse, mutect2, varscan2
- RNF123 | c.3692T>G p.L1231R | Missense Mutation (SNP) | VAF 42/528 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1370604144; called by muse, mutect2
- RNF144B | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 75/689 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52571776; called by muse, mutect2, varscan2
- RPA4 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 69/684 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100232092; called by muse, mutect2, varscan2
- RREB1 | c.2237A>G p.D746G | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1186850765; called by muse, mutect2
- RUFY1 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as rs779361259; called by muse, mutect2, varscan2
- RWDD2B | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 45/812 reads (6%) | catalogued as rs1296603003, COSV54502348; called by muse, mutect2
- RYR2 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 106/876 reads (12%) | catalogued as rs749567039, COSV63662584, COSV63694540; called by muse, mutect2, varscan2
- RYR2 | c.12221A>T p.E4074V | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63696500; called by muse, mutect2
- S1PR4 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.498); catalogued as rs200307755; called by muse, mutect2, varscan2
- SAFB | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 24/543 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1188708483; called by muse, mutect2
- SAFB2 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 31/515 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53043866, COSV99385989; called by muse, mutect2
- SEMA4C | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750799330, COSV59690923; called by muse, mutect2, varscan2
- SENP7 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 90/934 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs200753653; called by muse, mutect2
- SERPINA3 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs188602956; called by muse, mutect2, varscan2
- SERPINB9 | c.979A>G p.T327A | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV66234420; called by muse, mutect2, varscan2
- SETD1A | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as rs771053823, COSV52680345; called by muse, mutect2
- SF3B1 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 103/903 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59207702; called by muse, mutect2, varscan2
- SH3GL3 | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 27/405 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61058005; called by muse, mutect2
- SIRT1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1431102999; called by muse, mutect2
- SLC1A2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 35/1070 reads (3%) | catalogued as rs921441636, COSV53518336; called by muse, mutect2
- SLC22A2 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 33/596 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1346240034; called by muse, mutect2
- SLC25A15 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 31/496 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs531611390, COSV58558585; called by muse, mutect2
- SLC26A7 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 31/455 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1367413403; called by muse, mutect2
- SLC27A4 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 34/391 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.683); catalogued as rs138443340; called by muse, mutect2
- SLC29A4 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 28/692 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1468505354, COSV51875813; called by muse, mutect2
- SLC38A2 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 53/890 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs755513742, COSV56744249; called by muse, mutect2
- SLC39A1 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 23/731 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.375); catalogued as rs1254104650, COSV104410171; called by muse, mutect2
- SLC4A2 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs201086697, COSV59657692; called by muse, mutect2, varscan2
- SLC5A5 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 41/435 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs375999547; called by muse, mutect2
- SLC66A1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763092892, COSV64320952; called by muse, mutect2, varscan2
- SLC6A14 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 91/599 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782017676; called by muse, mutect2, varscan2
- SLC7A1 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101060188; called by muse, mutect2
- SLX4 | c.5080G>A p.A1694T | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as rs1218491919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD6 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 17/439 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs1331154068, COSV99993947; called by muse, mutect2
- SMC5 | c.1385A>G p.D462G | Missense Mutation (SNP) | VAF 91/899 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751992422; called by muse, mutect2, varscan2
- SMIM7 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.093); catalogued as rs753368172; called by muse, mutect2, varscan2
- SMS | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 68/656 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs752654736, COSV65115478; called by muse, mutect2, varscan2
- SNX20 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.297); catalogued as rs930507012; called by muse, mutect2
- SORCS3 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 98/563 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs766458554, COSV63795461; called by muse, mutect2, varscan2
- SPAG17 | c.5297G>A p.R1766H | Missense Mutation (SNP) | VAF 136/990 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs140894596, COSV60463670; called by muse, varscan2
- SPATA13 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 107/360 reads (30%) | catalogued as rs1371876337; called by muse, mutect2, varscan2
- SPEF2 | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 110/882 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763635089, COSV61547858; called by muse, mutect2, varscan2
- SPEG | c.3703C>T p.R1235C | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753756338; called by muse, mutect2
- SPEN | c.8486G>A p.R2829Q | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs1298693905; called by muse, mutect2, varscan2
- SPG7 | c.2041C>T p.R681W (on ENST00000268704; = p.R688W on NM_003119.4) | Missense Mutation (SNP) | VAF 27/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1249957920, COSV51954759; called by muse, mutect2
- SPHK1 | c.611G>A p.R204H (on ENST00000392496 / NM_001355139.2; = p.R218H on NM_021972.4) | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.286); catalogued as rs756281276; called by muse, mutect2, varscan2
- SPOCD1 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 55/390 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs748650368; called by muse, mutect2, varscan2
- SPRY4 | c.230C>T p.T77M (on ENST00000434127 / NM_001127496.3; = p.T100M on NM_030964.4) | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs774674946, CM133830, COSV59986194; called by muse, mutect2, varscan2
- SPRYD3 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs148811436; called by muse, mutect2
- SPTB | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs776814615, COSV67635244; called by muse, mutect2
- SRGAP2 | c.3031G>A p.A1011T (on ENST00000624873 / NM_001170637.4; = p.A1012T on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/584 reads (4%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.014); catalogued as rs782463648; called by muse, mutect2
- SRPRB | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 84/1124 reads (7%) | catalogued as rs749761078, COSV101524152; called by muse, mutect2
- SSC5D | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1041780494; called by muse, mutect2, varscan2
- STAC2 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 30/433 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs745556545; called by muse, mutect2
- STARD3 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 66/454 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs374855495; called by muse, mutect2, varscan2
- STOM | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1237373752, COSV54416934, COSV54419472; called by muse, mutect2, varscan2
- STOX2 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs549196640, COSV57857932; called by muse, mutect2, varscan2
- SULT4A1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 44/734 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753786397; called by muse, mutect2
- SUMF1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 31/1155 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs1249221556, COSV55994224; called by muse, mutect2
- SVEP1 | c.3638G>A p.R1213H | Missense Mutation (SNP) | VAF 89/894 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs371387093; called by muse, mutect2
- SYNCRIP | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 26/828 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.586); catalogued as COSV62287603; called by muse, mutect2
- SYNGR1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs376781457; called by muse, mutect2, varscan2
- TAF1C | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 58/434 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs751167821, COSV58985975; called by muse, mutect2, varscan2
- TBC1D10C | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs748936871, COSV56703058; called by muse, mutect2, varscan2
- TBC1D24 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.563); catalogued as rs537705878, COSV53547918; called by muse, mutect2
- TBC1D9 | c.2557C>T p.R853W | Missense Mutation (SNP) | VAF 76/629 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs188270414; called by muse, mutect2, varscan2
- TCF7L2 | c.1156C>T p.R386W (on ENST00000355995 / NM_001367943.1; = p.R363W on NM_030756.5) | Missense Mutation (SNP) | VAF 45/436 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1427214163, COSV53336330, COSV53343980; called by muse, varscan2
- TECR | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 57/358 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs763449006, COSV53108136; called by muse, mutect2, varscan2
- TENM4 | c.5485C>T p.R1829C | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754872057, COSV99577223; called by muse, mutect2, varscan2
- TENT4A | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as rs1363683837, COSV50094937; called by muse, mutect2
- TENT5C | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs865949572, COSV65616506; called by muse, mutect2
- TEPSIN | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 60/420 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.085); catalogued as rs768246747, COSV56142125; called by muse, varscan2
- TET3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs771078078, COSV59881541; called by muse, mutect2, varscan2
- TEX264 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 66/563 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs375351243; called by muse, mutect2, varscan2
- TFPT | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs545448952, COSV100338121, COSV57837379; called by muse, mutect2, varscan2
- TGFB1I1 | c.593C>T p.P198L (on ENST00000394863 / NM_001042454.3; = p.P181L on NM_015927.4) | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749864372; called by muse, mutect2, varscan2
- TGFBRAP1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 84/530 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.102); catalogued as rs756026751, COSV51511746; called by muse, mutect2
- TH | c.538C>T p.R180C (on ENST00000381178 / NM_199292.3; = p.R149C on NM_000360.4) | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs779228923, COSV104408376; called by muse, mutect2
- THAP10 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 32/686 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs960240233, COSV99997768; called by muse, mutect2
- THAP9 | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 94/746 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs774769281, COSV100155645; called by muse, mutect2, varscan2
- THSD7B | c.2549G>A p.C850Y | Missense Mutation (SNP) | VAF 28/877 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55652175; called by muse, mutect2
- TIMMDC1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 74/1130 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs1236666566; called by muse, mutect2
- TKTL1 | c.789del p.I264Lfs*12 | Frame Shift Del (DEL) | VAF 74/534 reads (14%) | catalogued as COSV54213089; called by mutect2, varscan2
- TLN2 | c.7205C>T p.A2402V | Missense Mutation (SNP) | VAF 58/410 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs755528338, COSV100168653; called by muse, mutect2, varscan2
- TLNRD1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs115354729; called by muse, mutect2, varscan2
- TMED5 | c.287+1G>A p.X96_splice | Splice Site (SNP) | VAF 70/818 reads (9%) | catalogued as rs146147342; called by muse, mutect2
- TMEM104 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs758697178; called by muse, mutect2, varscan2
- TMEM119 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs376586495; called by muse, mutect2, varscan2
- TMEM132E | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 15/339 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100396431; called by muse, mutect2
- TMEM151B | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.197); catalogued as COSV65256406; called by muse, mutect2
- TMEM229A | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 47/484 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs570827304; called by muse, mutect2
- TMEM240 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.644); catalogued as rs1339640590; called by muse, mutect2
- TMEM25 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782062665, COSV100244756; called by muse, mutect2
- TMEM262 | c.275-7C>T | Splice Region (SNP) | VAF 10/163 reads (6%) | catalogued as rs970952133; called by muse, mutect2
- TMEM273 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 71/523 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs201671898, COSV65152808; called by muse, varscan2
- TMEM74 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 57/427 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61753521, COSV52462042; called by muse, mutect2, varscan2
- TMEM86A | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.515); catalogued as rs750692066, COSV55010397; called by muse, mutect2
- TMPRSS6 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 69/588 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as rs371788844; called by muse, mutect2, varscan2
- TNFRSF21 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 30/1142 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57279868, COSV99729235; called by muse, mutect2
- TNFSF14 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 36/371 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs760204853; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4735C>T p.R1579C | Missense Mutation (SNP) | VAF 79/475 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777352586; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 70/580 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.462); catalogued as rs757503738, COSV64102169; called by muse, mutect2
- TNKS1BP1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs878907511; called by muse, mutect2, varscan2
- TNP2 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1358246236; called by muse, mutect2
- TP53BP1 | c.3364A>G p.T1122A | Missense Mutation (SNP) | VAF 22/900 reads (2%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55499057; called by muse, mutect2
- TPCN1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 77/443 reads (17%) | catalogued as rs750786711; called by muse, mutect2, varscan2
- TPCN2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 67/546 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as rs767412783; called by muse, mutect2, varscan2
- TPK1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 30/976 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358881813, COSV100766196; called by muse, mutect2
- TRAPPC12 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.166); catalogued as COSV100160595; called by muse, mutect2, varscan2
- TRAPPC8 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 79/500 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs577803701, COSV51967695; called by muse, mutect2, varscan2
- TRIM50 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 191/493 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.271); catalogued as rs1554543509, COSV53091068; called by muse, mutect2, varscan2
- TRIM56 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs201906197, COSV100047284; called by muse, mutect2, varscan2
- TRPV6 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 40/618 reads (6%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs771971978; called by muse, mutect2
- TSC1 | c.1384T>G p.F462V | Missense Mutation (SNP) | VAF 121/1050 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.783); catalogued as COSV100052899; called by muse, mutect2, varscan2
- TSPAN1 | c.418T>C p.W140R | Missense Mutation (SNP) | VAF 43/588 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264083601; called by muse, mutect2
- TSPYL6 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 34/631 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.248); catalogued as COSV57816559; called by muse, mutect2
- TST | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 71/411 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs549953112; called by muse, mutect2, varscan2
- TTC12 | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1184967069; called by muse, mutect2
- TTC31 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs752905468, COSV52037139; called by muse, mutect2, varscan2
- TTC34 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.074); catalogued as rs780715170; called by muse, mutect2, varscan2
- TTC7A | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as rs559596886, COSV99766792; called by muse, mutect2, varscan2
- TTN | c.93946T>C p.Y31316H (on ENST00000591111; = p.Y23892H on NM_003319.4) | Missense Mutation (SNP) | VAF 45/538 reads (8%) | PolyPhen probably damaging (0.974); catalogued as rs1267513093; called by muse, mutect2
- TTN | c.88640C>T p.A29547V (on ENST00000591111; = p.A22123V on NM_003319.4) | Missense Mutation (SNP) | VAF 93/570 reads (16%) | PolyPhen probably damaging (0.997); catalogued as COSV100603867; called by muse, mutect2, varscan2
- TUBG2 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 48/402 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs552803297; called by muse, mutect2, varscan2
- TUBGCP3 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 49/868 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV56189248; called by muse, mutect2
- TULP1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs761667984; called by muse, mutect2
- TXN2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 47/557 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139984170; called by muse, mutect2
- TYK2 | c.3242C>T p.A1081V | Missense Mutation (SNP) | VAF 20/624 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV53386367; called by muse, mutect2
- TYRO3 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 62/964 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768420836, COSV55483763; called by muse, mutect2
- UBQLN3 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs144562442; called by muse, mutect2, varscan2
- UBR3 | c.2980C>T p.R994* | Nonsense Mutation (SNP) | VAF 113/960 reads (12%) | catalogued as rs1219172339; called by muse, mutect2, varscan2
- UBR4 | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 74/528 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1477290047, COSV64401354; called by muse, mutect2, varscan2
- UBXN6 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 30/401 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs368537262; called by muse, mutect2
- UGP2 | c.876C>T p.G292= | Splice Region (SNP) | VAF 64/374 reads (17%) | catalogued as rs1177583716, COSV61429167; called by muse, mutect2, varscan2
- UGT8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 106/701 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs114818124; called by muse, mutect2, varscan2
- USP13 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs548301289, COSV55869357; called by muse, varscan2
- USP9X | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 26/907 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61066284; called by muse, mutect2
- UTP20 | c.5110G>A p.A1704T | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs772682870, COSV55379325; called by muse, mutect2, varscan2
- UXS1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 48/828 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV51680837; called by muse, mutect2
- VAV3 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 93/710 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58378527; called by muse, mutect2, varscan2
- VCAN | c.3740A>G p.D1247G | Missense Mutation (SNP) | VAF 75/899 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); catalogued as rs962387228; called by muse, mutect2
- VDR | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 64/514 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as rs1359262907, COSV57469031; called by muse, mutect2, varscan2
- VPS13B | c.4780A>C p.N1594H | Missense Mutation (SNP) | VAF 37/1093 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62147632; called by muse, mutect2
- VWCE | c.2047G>A p.V683M | Missense Mutation (SNP) | VAF 35/337 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs767119125, COSV57111605, COSV57115648; called by muse, mutect2, varscan2
- WASHC2A | c.3092G>A p.R1031H | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555524419, COSV99254621; called by muse, mutect2
- WDR59 | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 78/630 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs781528626; called by mutect2, varscan2
- WDR62 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763168502, COSV54334269; called by muse, mutect2, varscan2
- WNT2B | c.410G>A p.R137Q (on ENST00000369684 / NM_024494.3; = p.R118Q on NM_004185.4) | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775324743, COSV56672776; called by muse, mutect2
- WNT3 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs778399124, COSV99843335; called by muse, mutect2, varscan2
- WNT5A | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 72/565 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763870268, COSV52837996; called by muse, mutect2, varscan2
- WNT7A | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166930553; called by muse, mutect2, varscan2
- XPO4 | c.2105A>G p.D702G | Missense Mutation (SNP) | VAF 112/730 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99689163; called by muse, mutect2, varscan2
- ZBTB38 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1357720132, COSV58540176; called by muse, mutect2
- ZDBF2 | c.5617A>G p.K1873E | Missense Mutation (SNP) | VAF 70/427 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746951501, COSV65623567; called by mutect2, varscan2
- ZFHX2 | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 17/381 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1037994291; called by muse, mutect2
- ZFHX3 | c.10810G>A p.A3604T | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs745550429, COSV51738826; called by muse, mutect2, varscan2
- ZFHX3 | c.6446G>A p.R2149H | Missense Mutation (SNP) | VAF 67/479 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51717751; called by muse, mutect2, varscan2
- ZG16B | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs927439407; called by muse, mutect2
- ZMYM5 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 92/662 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs573943099, COSV61987350; called by muse, mutect2, varscan2
- ZNF132 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 80/480 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.091); catalogued as rs372220297; called by muse, mutect2, varscan2
- ZNF133 | c.1585C>T p.R529* (on ENST00000316358 / NM_001352454.2; = p.R528* on NM_003434.7 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 51/317 reads (16%) | catalogued as rs1182684086, COSV100315235; called by muse, mutect2, varscan2
- ZNF169 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 17/142 reads (12%) | catalogued as rs146740357; called by muse, mutect2, varscan2
- ZNF202 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 88/560 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs202211601, COSV60247785; called by muse, mutect2, varscan2
- ZNF296 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99673897; called by muse, mutect2, varscan2
- ZNF30 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 98/500 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV100340352, COSV57852681; called by muse, mutect2, varscan2
- ZNF331 | c.639A>C p.K213N | Missense Mutation (SNP) | VAF 37/502 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53475019, COSV53478882; called by muse, mutect2
- ZNF343 | c.1012T>C p.S338P | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99601528; called by muse, mutect2, varscan2
- ZNF408 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 30/504 reads (6%) | catalogued as rs758273578, COSV61238848; called by muse, mutect2
- ZNF462 | c.3691G>A p.A1231T | Missense Mutation (SNP) | VAF 27/568 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52931405; called by muse, mutect2
- ZNF496 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 33/650 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54176849; called by muse, mutect2
- ZNF516 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV71586956; called by muse, mutect2
- ZNF517 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 34/489 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1363196418; called by muse, mutect2
- ZNF536 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs896581213, COSV62821835; called by muse, mutect2
- ZNF549 | c.1235C>T p.T412M (on ENST00000376233 / NM_001199295.2; = p.T399M on NM_153263.2) | Missense Mutation (SNP) | VAF 99/721 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs531934209, COSV53724847, COSV53728936; called by muse, mutect2, varscan2
- ZNF750 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 38/675 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as rs771100167; called by muse, mutect2
- ZNF791 | c.474A>C p.K158N | Missense Mutation (SNP) | VAF 44/842 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100589031, COSV100589110; called by muse, mutect2
- ZNRF4 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.207); catalogued as rs747674030, COSV55773369; called by muse, mutect2, varscan2
- ZRANB3 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 34/942 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.682); catalogued as COSV99923299; called by muse, mutect2
- ZSWIM2 | c.1643G>A p.C548Y | Missense Mutation (SNP) | VAF 64/947 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762446580; called by muse, mutect2
- ZZEF1 | c.7826G>A p.R2609Q | Missense Mutation (SNP) | VAF 65/482 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs756072923; called by muse, mutect2, varscan2
- ABCA2 | c.5139_5142dup p.F1715Afs*94 (on ENST00000614293; = p.F1685Afs*94 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 102/320 reads (32%) | called by mutect2, varscan2
- ABCA7 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 26/377 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCC9 | c.4577A>T p.E1526V | Missense Mutation (SNP) | VAF 102/1180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCD1 | c.1256T>C p.V419A | Missense Mutation (SNP) | VAF 53/488 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- AC126283.2 | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 26/764 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- ACIN1 | c.2483-4A>G | Splice Region (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- ACSF2 | c.1367A>G p.N456S | Missense Mutation (SNP) | VAF 20/567 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- ACSL6 | c.1303G>A p.A435T (on ENST00000379240; = p.A460T on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/817 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ACSM5 | c.1186T>C p.S396P | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ACSS3 | c.1790T>C p.V597A | Missense Mutation (SNP) | VAF 65/980 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2
- ACTL6A | c.110T>C p.F37S | Missense Mutation (SNP) | VAF 17/469 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- ACTR8 | c.394T>C p.S132P | Missense Mutation (SNP) | VAF 85/739 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACVR1 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 50/842 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ADAMTS1 | c.1394A>G p.D465G | Missense Mutation (SNP) | VAF 98/769 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS16 | c.1627T>C p.C543R | Missense Mutation (SNP) | VAF 44/636 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- ADAMTS6 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 41/692 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2
- ADAMTS6 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 67/1066 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS8 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 57/403 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY6 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADD2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 71/467 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ADGRA2 | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 28/690 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.049); called by muse, mutect2
- ADH7 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 32/952 reads (3%) | called by muse, mutect2
- AEBP2 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 60/1105 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- AGO1 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 27/1010 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AL645922.1 | c.1519A>G p.T507A | Missense Mutation (SNP) | VAF 78/604 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ALDH1A2 | c.1421A>G p.Y474C | Missense Mutation (SNP) | VAF 66/772 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ALLC | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 76/525 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ANAPC10 | c.558A>G p.*186Wext*2 | Nonstop Mutation (SNP) | VAF 28/368 reads (8%) | called by muse, mutect2
- ANKRD30B | c.616T>G p.C206G | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.135); called by muse, mutect2
- ANKRD36 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 60/960 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANKRD44 | c.552C>T p.G184= | Splice Region (SNP) | VAF 54/854 reads (6%) | called by muse, mutect2
- ANKRD55 | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 32/994 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.4); called by muse, mutect2
- ANXA1 | c.599A>G p.D200G | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ARHGAP11B | c.794A>G p.D265G | Missense Mutation (SNP) | VAF 81/580 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1B | c.3379T>C p.S1127P | Missense Mutation (SNP) | VAF 54/866 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARMCX2 | c.1678T>C p.S560P | Missense Mutation (SNP) | VAF 22/638 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- ARSL | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 77/794 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASB5 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 130/1139 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASF1A | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 39/644 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.413); called by muse, mutect2
- ATP10B | c.3014C>T p.A1005V | Missense Mutation (SNP) | VAF 150/779 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2C1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 76/618 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP7B | c.608A>G p.D203G | Missense Mutation (SNP) | VAF 94/651 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ATXN2L | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 65/416 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- AXIN2 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2
- B4GALT6 | c.758T>G p.L253R | Missense Mutation (SNP) | VAF 32/792 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- BARD1 | c.1769T>C p.V590A | Missense Mutation (SNP) | VAF 32/1168 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BAZ1B | c.4189A>G p.S1397G | Missense Mutation (SNP) | VAF 24/596 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- BOP1 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- BRD4 | c.1175A>G p.D392G | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); called by muse, mutect2
- BRWD1 | c.5150A>T p.N1717I | Missense Mutation (SNP) | VAF 110/832 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- BTBD17 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTK | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 48/790 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); called by muse, mutect2
- C1orf167 | c.4088C>T p.A1363V | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- C1orf74 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 34/467 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- CACNA1I | c.3842G>A p.R1281H | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CADM4 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 27/464 reads (6%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.995); called by muse, mutect2
- CAND2 | c.3047T>C p.F1016S | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAPN3 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 48/585 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); called by muse, mutect2
- CCDC166 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- CCDC89 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 26/666 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.381); called by muse, mutect2
- CDC37L1 | c.1004A>G p.D335G | Missense Mutation (SNP) | VAF 88/881 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- CDH20 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CDH9 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 44/752 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CES1 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 28/694 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.313); called by muse, mutect2
- CHD7 | c.6149G>A p.R2050Q | Missense Mutation (SNP) | VAF 48/860 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- CLASP1 | c.4442G>A p.R1481H | Missense Mutation (SNP) | VAF 56/874 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CLCN1 | c.224A>T p.D75V | Missense Mutation (SNP) | VAF 66/1242 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2
- CNDP2 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CNTRL | c.1879A>G p.T627A | Missense Mutation (SNP) | VAF 89/662 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL24A1 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A6 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 84/624 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- COMTD1 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- COMTD1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- COX15 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 55/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CPEB4 | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 139/849 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE5 | c.1393A>G p.I465V | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- CPXCR1 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 65/976 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- CPXM1 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2
- CR1 | c.2722A>T p.T908S | Missense Mutation (SNP) | VAF 100/1576 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.042); called by muse, mutect2
- CRYBG3 | c.6512T>C p.V2171A | Missense Mutation (SNP) | VAF 29/602 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.24); called by muse, mutect2
- CSE1L | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 88/1012 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.005); called by muse, mutect2
- CSRNP2 | c.1632A>G p.*544Wext*82 | Nonstop Mutation (SNP) | VAF 44/211 reads (21%) | called by muse, mutect2, varscan2
- CTU1 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CUL9 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 24/651 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); called by muse, mutect2
- CXADR | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 56/695 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CYLC2 | c.79T>C p.S27P | Missense Mutation (SNP) | VAF 114/683 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- CYP2C9 | c.475A>C p.T159P | Missense Mutation (SNP) | VAF 39/580 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2
- CYP2W1 | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2
988 further variants in this file (333 protein-altering or splice-affecting, 451 silent, 204 other) are not listed here.
